Somatic mutation profile of tumor specimen 0DF02W from CCDI case PBBRGM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.2 years (1,889 days).
Specimen 0DF02W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c969b770-7ff5-4a96-83aa-a7e877a09fc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF02Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37792d0b-e372-4431-88e3-e46c1f04df39

The open-access MAF lists 95 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Intron 7, 3'UTR 6, 5'UTR 4, Splice Region 2, Frame Shift Del 2, 5'Flank 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 251/275 reads (91%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- AGMAT | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1387820277; called by muse, mutect2, varscan2
- AIFM2 | c.969G>A p.P323= | Splice Region (SNP) | VAF 129/315 reads (41%) | catalogued as rs774392642, COSV100325771; called by muse, mutect2
- CADPS2 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 93/426 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV57355189; called by muse, mutect2, varscan2
- CCDC171 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1388478271; called by muse, mutect2, varscan2
- CHRD | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 124/302 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs980833271, COSV52608137; called by muse, mutect2
- CLDN23 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 44/530 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.027); catalogued as rs1005678106; called by muse, mutect2
- GLIS3 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 102/440 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs748922836, COSV60936492; called by muse, mutect2, varscan2
- INTS6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 116/830 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV60876417; called by muse, mutect2, varscan2
- MYCT1 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 142/391 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs199999351, COSV65891829; called by muse, mutect2, varscan2
- NUDCD2 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 118/699 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1486748377; called by muse, mutect2, varscan2
- OR4C16 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 85/562 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs781407515; called by muse, mutect2, varscan2
- RCC1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.111); catalogued as rs753925071; called by mutect2, varscan2
- RNF225 | c.214del p.D72Tfs*? | Frame Shift Del (DEL) | VAF 59/268 reads (22%) | catalogued as COSV52191433; called by mutect2, varscan2
- SLC15A5 | c.1441A>C p.T481P | Missense Mutation (SNP) | VAF 140/475 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs368362486; called by muse, mutect2, varscan2
- TCTN2 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.192); catalogued as COSV57633101; called by muse, mutect2, varscan2
- TEX14 | c.4261G>C p.V1421L (on ENST00000240361 / NM_001201457.2; = p.V1375L on NM_031272.5) | Missense Mutation (SNP) | VAF 51/501 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53621364, COSV53623584; called by muse, mutect2, varscan2
- TINAG | c.19A>T p.I7F | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV52510798; called by muse, mutect2, varscan2
- TNPO1 | c.1292C>A p.A431E | Missense Mutation (SNP) | VAF 56/610 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61522234; called by muse, mutect2
- UXS1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 163/550 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1327555218, COSV51680035; called by muse, mutect2, varscan2
- WDR18 | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99242932; called by muse, mutect2, varscan2
- ACSM1 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ADAMTS9 | c.2616T>G p.I872M | Missense Mutation (SNP) | VAF 113/588 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- AMPH | c.1730C>G p.P577R | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ARHGAP44 | c.2359G>T p.G787W | Missense Mutation (SNP) | VAF 228/360 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ASTN2 | c.2769G>C p.K923N (on ENST00000313400 / NM_001365069.1; = p.K872N on NM_014010.5) | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1C | c.1728C>A p.Y576* | Nonsense Mutation (SNP) | VAF 51/356 reads (14%) | called by muse, mutect2, varscan2
- CARD9 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL10A1 | c.1640C>G p.T547R | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ELFN1 | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAT3 | c.6481A>G p.K2161E | Missense Mutation (SNP) | VAF 70/453 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FBN2 | c.8380C>A p.L2794I | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FLG | c.526A>C p.N176H | Missense Mutation (SNP) | VAF 104/506 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.43); called by muse, mutect2
- FOXO1 | c.38del p.D13Afs*59 | Frame Shift Del (DEL) | VAF 62/170 reads (36%) | called by mutect2, varscan2
- FREM3 | c.383A>C p.H128P | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA8M | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IKBIP | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 28/798 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); called by muse, mutect2
- KAT2B | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- KCNAB1 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 167/333 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by mutect2, varscan2
- KTN1 | c.2384T>C p.L795P | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MGAM | c.5253C>A p.F1751L | Missense Mutation (SNP) | VAF 209/491 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYC | c.1103A>G p.N368S (on ENST00000377970; = p.N383S on NM_002467.6) | Missense Mutation (SNP) | VAF 100/1626 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- NFXL1 | c.834C>G p.C278W | Missense Mutation (SNP) | VAF 73/474 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OCSTAMP | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLEKHM3 | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKAG1 | c.537+8C>A | Splice Region (SNP) | VAF 45/301 reads (15%) | called by muse, mutect2, varscan2
- PRR29 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 63/528 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PTPN11 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 65/383 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPN23 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QSER1 | c.3686T>C p.F1229S (on ENST00000399302; = p.F1358S on NM_001076786.3) | Missense Mutation (SNP) | VAF 38/596 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2
- RGS20 | c.841C>G p.R281G (on ENST00000297313 / NM_170587.4; = p.R134G on NM_003702.4) | Missense Mutation (SNP) | VAF 96/1185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SHISA5 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SV2C | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 244/538 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- THBS1 | c.2864C>A p.T955N | Missense Mutation (SNP) | VAF 87/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- THSD7B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 48/301 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TLE2 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TMEM39A | c.1096A>G p.N366D | Missense Mutation (SNP) | VAF 72/369 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF786 | c.1649G>C p.G550A | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- ADGRA2 | c.3756G>A p.P1252= | Silent (SNP) | VAF 80/496 reads (16%) | catalogued as rs1395657299, COSV55105846; called by muse, mutect2, varscan2
- CALR3 | c.795G>A p.L265= | Silent (SNP) | VAF 37/292 reads (13%) | called by muse, mutect2, varscan2
- CDR2 | c.1290T>C p.F430= | Silent (SNP) | VAF 136/259 reads (53%) | catalogued as rs755150916; called by muse, mutect2, varscan2
- FBXL8 | c.159A>G p.E53= | Silent (SNP) | VAF 51/275 reads (19%) | called by muse, mutect2, varscan2
- FFAR2 | c.822T>C p.Y274= | Silent (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- FLG | c.501T>A p.T167= | Silent (SNP) | VAF 102/546 reads (19%) | catalogued as rs779699797; called by muse, mutect2
- FYCO1 | c.4104T>C p.F1368= | Silent (SNP) | VAF 137/292 reads (47%) | called by muse, mutect2, varscan2
- IP6K3 | c.885G>A p.R295= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV53390103; called by muse, mutect2, varscan2
- ITPKB | c.1299C>T p.G433= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as rs550313561, COSV55269114; called by muse, mutect2, varscan2
- KRTAP27-1 | c.609A>G p.Q203= | Silent (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- MS4A15 | c.327C>T p.V109= (on ENST00000405633 / NM_001098835.2; = p.V16= on NM_152717.3) | Silent (SNP) | VAF 38/369 reads (10%) | called by muse, mutect2
- MYO3B | c.459C>A p.I153= | Silent (SNP) | VAF 72/530 reads (14%) | called by muse, mutect2, varscan2
- PELP1 | c.837C>T p.Y279= | Silent (SNP) | VAF 110/300 reads (37%) | catalogued as rs766804631; called by muse, mutect2, varscan2
- PHC3 | c.888A>G p.S296= (on ENST00000494943 / NM_001308116.2; = p.S308= on NM_024947.4) | Silent (SNP) | VAF 78/529 reads (15%) | called by muse, mutect2, varscan2
- RADIL | c.1803G>C p.S601= | Silent (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
- RIPK2 | c.1518A>G p.V506= | Silent (SNP) | VAF 77/1160 reads (7%) | called by muse, mutect2
- SMYD3 | c.327C>A p.V109= (on ENST00000490107 / NM_001375962.1; = p.V50= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/350 reads (19%) | catalogued as COSV101194216; called by muse, mutect2, varscan2
- ST14 | c.162C>T p.R54= | Silent (SNP) | VAF 52/384 reads (14%) | catalogued as COSV53832995; called by muse, mutect2, varscan2
- ZNF382 | c.21G>T p.V7= | Silent (SNP) | VAF 81/350 reads (23%) | called by muse, mutect2, varscan2
- CASP4 | c.*5+82_*5+86del | Intron (DEL) | VAF 30/156 reads (19%) | called by mutect2, varscan2
- CDC37 | c.-18C>G | 5'UTR (SNP) | VAF 10/51 reads (20%) | catalogued as rs761787036; called by muse, mutect2, varscan2
- CSF3R | c.*67G>C | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- DMP1 | c.*15A>G | 3'UTR (SNP) | VAF 27/152 reads (18%) | catalogued as rs771691318; called by muse, mutect2, varscan2
- ELOBP3 | chr2:48776371 ins C | 5'Flank (INS) | VAF 52/371 reads (14%) | catalogued as rs1242628969; called by mutect2, varscan2
- FAM174B | c.-9C>T | 5'UTR (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- GABRA1 | c.*28T>C | 3'UTR (SNP) | VAF 30/147 reads (20%) | called by muse, mutect2, varscan2
- GPX6 | c.*85G>T | 3'UTR (SNP) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- KCNH5 | c.-56G>A | 5'UTR (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- KLRC1 | c.590+23A>G | Intron (SNP) | VAF 75/504 reads (15%) | catalogued as rs780129468; called by muse, mutect2, varscan2
- LDLRAD2 | c.*1882C>A | 3'UTR (SNP) | VAF 41/159 reads (26%) | called by muse, mutect2, varscan2
- MBOAT1 | c.99+34_99+41del | Intron (DEL) | VAF 18/65 reads (28%) | called by mutect2, varscan2
- MORF4L1 | c.40+55G>T | Intron (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- NIPAL4 | c.-12G>A | 5'UTR (SNP) | VAF 30/160 reads (19%) | catalogued as rs1350526878; called by muse, mutect2, varscan2
- SEC14L4 | c.912-41G>A | Intron (SNP) | VAF 126/324 reads (39%) | called by muse, mutect2, varscan2
- SOHLH1 | c.*660C>A | 3'UTR (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23561G>T | Intron (SNP) | VAF 42/188 reads (22%) | catalogued as COSV100529986, COSV100531082; called by muse, mutect2, varscan2
- ZCCHC17 | c.318-18G>T | Intron (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
